Somatic mutation profile of tumor specimen ASCProject_0068_T1_WES (aliquot ASCProject_0068_T1_WES_1) from CMI case ASCProject_0068, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 55.8 years (20,388 days).
Specimen ASCProject_0068_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 998b03bf-d962-4727-a17a-e87c3801c17d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0068_SALIVA (Saliva), aliquot ASCProject_0068_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f27f69bc-b7d0-42bf-b681-d0c7a7c341ea

The open-access MAF lists 53 somatic variants for this specimen: 34 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 16, Intron 3, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL1 | c.2305G>A p.A769T (on ENST00000340736 / NM_001008701.3; = p.A764T on NM_014921.5) | Missense Mutation (SNP) | VAF 84/412 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.216); catalogued as COSV61564099; called by muse, mutect2, varscan2
- ARHGAP23 | c.4207T>C p.W1403R | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1344337594; called by muse, mutect2, varscan2
- BBC3 | c.559C>G p.R187G (on ENST00000449228 / NM_001127240.3; = p.Y152* on NM_014417.5) | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs1467397924, COSV56262781; called by muse, mutect2, varscan2
- C22orf31 | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV53311236; called by muse, mutect2, varscan2
- CIP2A | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780556414; called by muse, mutect2, varscan2
- DDR1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs373564993, COSV100241736; called by muse, mutect2, varscan2
- DEUP1 | c.1601C>G p.T534R | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV53210404; called by muse, mutect2, varscan2
- DPY19L4 | c.1202G>T p.C401F | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1357487659; called by muse, mutect2, varscan2
- DSCAML1 | c.3709G>A p.V1237I (on ENST00000321322; = p.V1177I on NM_020693.4) | Missense Mutation (SNP) | VAF 109/283 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs544850403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.5558+1G>C p.X1853_splice | Splice Site (SNP) | VAF 29/86 reads (34%) | catalogued as COSV62091454; called by muse, mutect2, varscan2
- FLCN | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 132/242 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.118); catalogued as rs1187982450; called by muse, mutect2, varscan2
- FSTL3 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs568510894; called by muse, mutect2, varscan2
- KLHL31 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145438022; called by muse, mutect2, varscan2
- PPARGC1A | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs143962880, COSV53524541; called by muse, mutect2, varscan2
- SCG2 | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 47/340 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV59538889; called by muse, mutect2, varscan2
- SRA1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs760956606; called by muse, mutect2, varscan2
- STS | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259321805; called by muse, mutect2, varscan2
- TPX2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV55917293; called by muse, mutect2, varscan2
- ADAM21 | c.913A>T p.S305C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ALKBH3 | c.500A>G p.E167G | Missense Mutation (SNP) | VAF 124/358 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ARHGAP24 | c.1679G>T p.C560F (on ENST00000395184 / NM_001025616.3; = p.C467F on NM_031305.3) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ARMH4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ASTN2 | c.1847G>T p.C616F (on ENST00000313400 / NM_001365069.1; = p.C565F on NM_014010.5) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C20orf203 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CMYA5 | c.6500C>A p.P2167H | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- KANSL1 | c.611dup p.M205Yfs*9 | Frame Shift Ins (INS) | VAF 26/115 reads (23%) | called by mutect2, pindel, varscan2
- KMT2D | c.9872_9882del p.P3291Hfs*6 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, varscan2
- LHFPL4 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); called by muse, mutect2
- MFSD2B | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ODF1 | c.645C>A p.C215* | Nonsense Mutation (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- SPATA31D3 | c.2689C>A p.Q897K | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TMEM132E | c.2015C>T p.T672I (on ENST00000321639; = p.T762I on NM_001304438.2) | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- UNC13C | c.3947T>G p.V1316G | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZDBF2 | c.3113G>A p.G1038D | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CNTNAP4 | c.3573C>T p.V1191= | Silent (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- COL5A3 | c.816C>G p.T272= | Silent (SNP) | VAF 72/165 reads (44%) | called by muse, mutect2, varscan2
- EHD1 | c.1335G>A p.K445= | Silent (SNP) | VAF 141/475 reads (30%) | called by muse, mutect2, varscan2
- EYA2 | c.648C>A p.S216= | Silent (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- FAM71E2 | c.2226C>A p.P742= | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- FAT1 | c.13707C>T p.D4569= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs745595921, COSV71674460; called by muse, mutect2, varscan2
- H1-7 | c.405G>A p.A135= | Silent (SNP) | VAF 141/311 reads (45%) | catalogued as COSV58602842; called by muse, mutect2, varscan2
- IL1RAP | c.720A>C p.A240= | Silent (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- INHBE | c.804C>A p.P268= | Silent (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- MSX2 | c.591G>A p.A197= | Silent (SNP) | VAF 68/217 reads (31%) | catalogued as rs150352201, COSV53326345; called by muse, mutect2, varscan2
- PIEZO1 | c.2511G>T p.L837= | Silent (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- RBCK1 | c.132A>G p.Q44= | Silent (SNP) | VAF 71/202 reads (35%) | called by muse, mutect2, varscan2
- SETBP1 | c.4020A>G p.L1340= | Silent (SNP) | VAF 19/292 reads (7%) | catalogued as COSV56334133; called by muse, mutect2
- SLC22A31 | c.265C>T p.L89= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1214188771; called by muse, mutect2, varscan2
- SUN2 | c.1731C>T p.F577= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs1010902420; called by muse, mutect2, varscan2
- UPK3B | c.663G>A p.A221= (on ENST00000257632; = p.R193Q on NM_001347684.2) | Silent (SNP) | VAF 48/259 reads (19%) | catalogued as rs201500728; called by muse, mutect2, varscan2
- ARHGAP15 | c.1003+31267G>A | Intron (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- KLRC2 | c.585-68G>A | Intron (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- ZNF609 | c.747+24G>T | Intron (SNP) | VAF 72/240 reads (30%) | called by muse, mutect2, varscan2
